Surgical pathology report (de-identified scan), TCGA case TCGA-BG-A0YV, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-BG-A0YV-01A (Primary Tumor).

PATIENT HISTORY:

CHIEF COMPLAINT/ PRE-OP/ POST-OP DIAGNOSIS: Endometrial cancer.
LMP DATE: Not available.

PROCEDURE: Robot assist total abdominal hysterectomy bilateral salpingo-oophorectomy, pelvic lymph node dissection.
SPECIFIC CLINICAL QUESTION: Not provided.

OUTSIDE TISSUE DIAGNOSIS: Not provided.

PRIOR MALIGNANCY: Not provided.

CHEMORADIATION THERAPY: Not provided.

OTHER DISEASES: Not provided.

1CD-0-3

adenocarcinoma, serous, NOS 8441/3

Site: endometrium C54.1 for 5/2/11

FINAL DIAGNOSIS:

PART 1: LYMPH NODE, LEFT COMMON AND PERIAORTIC -
NO METASTATIC CARCINOMA IS IDENTIFIED IN ONE LYMPH NODE (0/1).

PART 2: LYMPH NODES, RIGHT COMMON AND PERIAORTIC -
NO METASTATIC ADENOCARCINOMA IDENTIFIED IN TWO LYMPH NODES (0/2).

PART 3: UTERUS, BILATERAL ADNEXA, ROBOT ASSISTED TOTAL ABDOMINAL HYSTERECTOMY AND BILATERAL SALPINGO-OOPHORECTOMY -
A. CHRONIC ENDOCERVIX WITH NABOTHIAN CYSTS; MICROSCOPIC ADENOCARCINOMA EXTERNALLY INVOLVES THE DEEP SURFACE OF THE CERVIX.
B. SEROUS ENDOMETRIAL ADENOCARCINOMA, NUCLEAR GRADE 3.
C. TUMOR EXTENDS THROUGH THE FULL THICKNESS OF THE MYOMETRIUM WITH SEROSAL INVOLVEMENT.
D. LYMPHOVASCULAR SPACE INVASION IS PRESENT.
E. BACKGROUND LEIOMYOMAS.
F. MICROSCOPIC BILATERAL PERITUBAL METASTATIC INVOLVEMENT, BILATERAL.
G. MICROSCOPIC BILATERAL OVARIAN INVOLVEMENT BY METASTATIC ADENOCARCINOMA.

PART 4: LYMPH NODES, RIGHT PELVIC, LYMPH NODE DISSECTION -
NO METASTATIC ADENOCARCINOMA IDENTIFIED IN NINE LYMPH NODES (0/9).

PART 5: LYMPH NODES, LEFT PELVIC, LYMPH NODE DISSECTION -
NO METASTATIC ADENOCARCINOMA IDENTIFIED IN EIGHT LYMPH NODES (0/8).

COMMENT:

Companion pelvic wash cytology specimen [REDACTED] is negative.

**CASE SYNOPSIS:**

SYNOPTIC - PRIMARY UTERINE ENDOMETRIAL CARCINOMA & CARCINOSARCOMA : HYSTERECTOMY SPECIMENS

TUMOR TYPE: Serous adenocarcinoma
HISTOLOGIC GRADE (epithelial neoplasm) [combined architectural and nuclear]: Poorly differentiated (FIGO 3)

ARCHITECTURAL GRADE: Poorly differentiated
NUCLEAR GRADE: Grade 3

TUMOR SIZE: Maximum dimension: 40 mm

PERCENT OF ENDOMETRIAL SURFACE INVOLVEMENT:

DEPTH OF INVASION: Anterior endomyometrium: 80 %, Posterior endomyometrium: 80 %
MARGINS OF RESECTION: Into serosa

ANGIOLYMPHATIC INVASION: Vaginal margin is negative for tumor, Parametrium margin is negative for tumor

OTHER: Yes

MITOTIC RATE: Leiomyoma

LYMPH NODES POSITIVE: Mitotic rate: 20 / 10 HPF

LYMPH NODES EXAMINED: Number of lymph nodes positive: 0

EXTRANODAL EXTENSION: Total number of lymph nodes examined: 20

DISTANT METASTASES (Excludes metastases to vagina, pelvic serosa, and adnexa. Includes lymph nodes other than regional lymph nodes.): No

Present

T STAGE, PATHOLOGIC: pT3a

N STAGE, PATHOLOGIC: pN0

M STAGE, PATHOLOGIC: Not applicable

FIGO STAGE: IIIA

RESIDUAL TUMOR: RX

for 5/2/11

Source: NCI Genomic Data Commons file 279e10b4-76ba-4a73-98bf-133f80f01fc9 (TCGA-BG-A0YV.D037EFD1-22CB-43FE-BE0A-F2189C5FB202.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).